CCDI case PBCEND — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/251d1ea4-557a-4d7b-bf8f-d26ad2493773

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Synovial sarcoma, spindle cell: ICD-O-3 morphology code: 9041/3; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 12.5 years (4,558 days).

Biospecimens (3 samples)
- Sample 0DQB22: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQB2K: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQB2Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
